Somatic mutation profile of tumor specimen MP2PRT-PATCEJ-TMP1-A (aliquot MP2PRT-PATCEJ-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATCEJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,944 days).
Specimen MP2PRT-PATCEJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0df97e06-e0dc-4bef-85cc-3cc98f90e515.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCEJ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCEJ-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bce24a8e-b842-4dd9-9b2e-3e4b0813df7c

The open-access MAF lists 168 somatic variants for this specimen: 131 protein-altering or splice-affecting, 31 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 31, Nonsense Mutation 18, Intron 4, Splice Site 3, Frame Shift Del 2, 3'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 12/304 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2
- ACD | c.1374C>G p.F458L (on ENST00000620338; = p.F369L on NM_022914.3) | Missense Mutation (SNP) | VAF 101/411 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1308443875; called by muse, mutect2, varscan2
- ACTBL2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 15/422 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1220404614, COSV70661390; called by muse, mutect2
- ADAM12 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64103789; called by muse, mutect2, varscan2
- ALMS1 | c.6224C>T p.S2075L | Missense Mutation (SNP) | VAF 154/342 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as rs755304222; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4063G>T p.D1355Y | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784294; called by muse, mutect2
- AP002748.5 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs759763673, COSV59152593; called by muse, mutect2, varscan2
- BAAT | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 22/443 reads (5%) | catalogued as COSV52287763; called by muse, mutect2
- BRPF3 | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 18/292 reads (6%) | catalogued as COSV100326287; called by muse, mutect2
- BUD13 | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 22/346 reads (6%) | catalogued as COSV52768297; called by muse, mutect2
- C12orf45 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 22/401 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.55); catalogued as COSV55012525; called by muse, mutect2
- CECR2 | c.2140G>A p.G714R (on ENST00000342247 / NM_001290047.2; = p.G531R on NM_001290046.1) | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs375149434; called by muse, mutect2, varscan2
- CEP164 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs764739972; called by muse, mutect2, varscan2
- CGAS | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 103/311 reads (33%) | catalogued as COSV64808772; called by muse, mutect2, varscan2
- CHAF1B | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.303); catalogued as rs778139508; called by muse, mutect2, varscan2
- CRNN | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 177/461 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201228418; called by muse, mutect2, varscan2
- DNAH10 | c.10491C>G p.I3497M (on ENST00000409039; = p.I3436M on NM_207437.3) | Missense Mutation (SNP) | VAF 107/497 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762906208; called by muse, mutect2, varscan2
- EVX1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 29/849 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1011658779; called by muse, mutect2
- FAM219A | c.346G>A p.D116N (on ENST00000445726; = p.D99N on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52619608; called by muse, mutect2
- FAT1 | c.11219G>C p.G3740A | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV71674867; called by muse, mutect2
- FNIP2 | c.3083C>G p.S1028C | Missense Mutation (SNP) | VAF 19/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476143526; called by muse, mutect2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 140/553 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GNPTAB | c.3576C>G p.F1192L | Missense Mutation (SNP) | VAF 142/279 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV54777402; called by muse, mutect2, varscan2
- IGSF9 | c.2168C>T p.S723L (on ENST00000368094 / NM_001135050.2; = p.S707L on NM_020789.4) | Missense Mutation (SNP) | VAF 164/379 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs1486044979, COSV63639555; called by muse, mutect2, varscan2
- IL7R | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 163/420 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100286319; called by muse, mutect2
- ITGA8 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as rs200233925, COSV65226596; called by muse, mutect2
- KIAA0232 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs1296861973; called by muse, mutect2
- KRT77 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs200529529; called by muse, mutect2, varscan2
- MANEA | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 47/256 reads (18%) | catalogued as rs762074058; called by muse, mutect2
- MEIOC | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV63439753; called by muse, mutect2
- MT1H | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV60090520; called by muse, mutect2, varscan2
- MYOF | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761109116; called by muse, mutect2
- NEO1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs562576846; called by muse, mutect2, varscan2
- NLN | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV66766768; called by muse, mutect2
- NR0B1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV66764902; called by muse, mutect2
- NR3C1 | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 18/332 reads (5%) | catalogued as COSV99196622; called by muse, mutect2
- OR6C2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV59516477, COSV59516705; called by muse, mutect2
- PCDHA13 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 24/626 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.417); catalogued as rs376943163; called by muse, mutect2
- PWWP3B | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 198/316 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV61799181; called by muse, mutect2, varscan2
- RGPD4 | c.1821G>A p.W607* | Nonsense Mutation (SNP) | VAF 38/262 reads (15%) | catalogued as COSV61749383; called by muse, mutect2, varscan2
- RIMBP2 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55474686; called by muse, mutect2, varscan2
- RNF183 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 13/382 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.776); catalogued as COSV104401042; called by muse, mutect2
- RUBCN | c.2469C>G p.F823L | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.336); catalogued as rs770670830; called by muse, mutect2, varscan2
- RUSC1 | c.761C>G p.T254S | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52740389; called by muse, mutect2
- SLC7A6OS | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs991229886, COSV50449929; called by muse, mutect2, varscan2
- SOCS7 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as rs765595674; called by muse, mutect2
- SPATA31A3 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 74/1330 reads (6%) | catalogued as rs1479462260; called by muse, mutect2
- SYNE2 | c.3639-1G>C p.X1213_splice | Splice Site (SNP) | VAF 12/234 reads (5%) | catalogued as rs1308678682; called by muse, mutect2
- TJP1 | c.4576C>T p.R1526* | Nonsense Mutation (SNP) | VAF 20/453 reads (4%) | catalogued as COSV100632399; called by muse, mutect2
- TMEM132E | c.398C>G p.S133W | Missense Mutation (SNP) | VAF 27/573 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100396439, COSV100396697; called by muse, mutect2
- TMEM17 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 11/383 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV59022659; called by muse, mutect2
- TONSL | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs1357919581; called by muse, mutect2
- TRAPPC8 | c.3637C>T p.H1213Y | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs746544816; called by muse, mutect2, varscan2
- TUBGCP2 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs146959915; called by muse, varscan2
- WWP1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55357245; called by muse, mutect2
- APC | c.4450G>A p.D1484N | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ARGLU1 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 118/543 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, varscan2
- ARX | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 276/402 reads (69%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1QL2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 248/699 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CAB39 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- CCDC85A | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 22/389 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDCA7 | c.467C>G p.S156* (on ENST00000347703 / NM_145810.3; = p.S235* on NM_031942.5) | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- CFTR | c.651G>C p.E217D | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- CHD5 | c.3829G>C p.E1277Q | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2
- CNKSR2 | c.1952C>G p.A651G | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- COL12A1 | c.8591C>T p.S2864F | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2
- CPLX4 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- CYRIB | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- DHX37 | c.1128G>C p.E376D | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- DLG2 | c.250A>G p.T84A (on ENST00000650630 / NM_001351274.2; = p.T47A on NM_001142699.3) | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DNAH8 | c.9934C>G p.Q3312E | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.06); called by muse, mutect2
- DST | c.4330G>A p.E1444K (on ENST00000361203 / NM_001374722.1; = p.E1118K on NM_015548.5) | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM135B | c.3968C>T p.S1323L | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM161B | c.1963G>C p.E655Q (on ENST00000651776; = p.E592Q on NM_152445.3) | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2
- FAM3B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- FBXO21 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 193/471 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- FDPS | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- FLII | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- FOXP2 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 126/284 reads (44%) | called by muse, mutect2, varscan2
- GABRG3 | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GALNT6 | c.1282C>G p.Q428E | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GPR179 | c.3975G>C p.E1325D (on ENST00000621958; = p.E1324D on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/562 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.205); called by muse, mutect2
- GREB1L | c.3242C>G p.S1081* | Nonsense Mutation (SNP) | VAF 24/393 reads (6%) | called by muse, mutect2
- H4C11 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HELQ | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- INTS1 | c.1737G>C p.Q579H | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.121); called by muse, varscan2
- KLHL29 | c.2260C>G p.Q754E | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2
- KRIT1 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACC1 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 20/391 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.362); called by muse, mutect2
- MAST3 | c.2609G>A p.R870K | Missense Mutation (SNP) | VAF 21/600 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- MFAP4 | c.540_541del p.H180Qfs*69 | Frame Shift Del (DEL) | VAF 58/249 reads (23%) | called by pindel, varscan2
- MINAR1 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 23/512 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- MPDZ | c.4372C>T p.Q1458* | Nonsense Mutation (SNP) | VAF 89/188 reads (47%) | called by muse, mutect2, varscan2
- MYCBP2 | c.9083C>G p.A3028G (on ENST00000357337; = p.A3066G on NM_015057.5) | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYLIP | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYORG | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 204/546 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.25); called by muse, mutect2
- NKTR | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 11/393 reads (3%) | called by muse, mutect2
- NLRP1 | c.2049G>C p.E683D | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.03); called by muse, mutect2
- NXF1 | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2
- OR4N2 | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 48/884 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- P2RY4 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- PARP14 | c.4149G>A p.M1383I | Missense Mutation (SNP) | VAF 149/395 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PCDHA10 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2
- PHLPP1 | c.4970_4971insAG p.P1658Gfs*22 | Frame Shift Ins (INS) | VAF 162/420 reads (39%) | called by mutect2, varscan2*
- PHLPP1 | c.4972_4973del p.P1658Gfs*3 | Frame Shift Del (DEL) | VAF 165/427 reads (39%) | called by mutect2, varscan2*
- PLK4 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.614); called by muse, mutect2
- PNKD | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PODXL2 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 87/291 reads (30%) | called by muse, mutect2, varscan2
- QRICH1 | c.2217G>A p.W739* | Nonsense Mutation (SNP) | VAF 110/325 reads (34%) | called by muse, mutect2, varscan2
- RASIP1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); called by muse, mutect2
- RNF123 | c.3825-1G>C p.X1275_splice | Splice Site (SNP) | VAF 17/280 reads (6%) | called by muse, mutect2
- RUSC1 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SACS | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SCN2A | c.5386G>C p.E1796Q | Missense Mutation (SNP) | VAF 151/373 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SCN7A | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SELENOP | c.610C>G p.H204D | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.266); called by muse, mutect2
- SERPINA4 | c.921G>C p.K307N | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLC45A4 | c.517G>A p.D173N (on ENST00000517878 / NM_001286646.2; = p.D122N on NM_001080431.2) | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A1 | c.2232G>C p.L744F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.041); called by muse, mutect2
- SMIM31 | c.113-1G>C p.X38_splice | Splice Site (SNP) | VAF 36/188 reads (19%) | called by muse, mutect2, varscan2
- SNCAIP | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- SORCS1 | c.2780A>G p.Y927C | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- SZT2 | c.2753G>C p.G918A | Missense Mutation (SNP) | VAF 164/425 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TET2 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 224/562 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TRPA1 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2
- UBA2 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UNC80 | c.4810G>A p.E1604K | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USP24 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 9/277 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- WDR5 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YBEY | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- ZNF622 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANKRD17 | c.3858C>G p.L1286= | Silent (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- ARHGEF15 | c.1233C>G p.L411= | Silent (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- CCDC17 | c.1011G>A p.P337= | Silent (SNP) | VAF 15/386 reads (4%) | catalogued as rs1229681658; called by muse, mutect2
- CFAP97D2 | c.297C>T p.H99= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- CHRNB4 | c.507C>G p.L169= | Silent (SNP) | VAF 14/400 reads (4%) | catalogued as COSV55714723; called by muse, mutect2
- CPT2 | c.945G>T p.L315= | Silent (SNP) | VAF 25/460 reads (5%) | called by muse, mutect2
- DCC | c.1842A>G p.T614= | Silent (SNP) | VAF 11/259 reads (4%) | called by muse, mutect2
- DDR2 | c.24C>G p.L8= | Silent (SNP) | VAF 72/272 reads (26%) | catalogued as rs1268092901; called by muse, varscan2
- DNHD1 | c.852G>A p.L284= | Silent (SNP) | VAF 77/343 reads (22%) | called by muse, mutect2, varscan2
- EGFL6 | c.1113G>A p.V371= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- EHF | c.642C>T p.R214= | Silent (SNP) | VAF 64/261 reads (25%) | catalogued as rs569349541; called by muse, varscan2
- FA2H | c.99C>G p.L33= | Silent (SNP) | VAF 21/730 reads (3%) | called by muse, mutect2
- INTS1 | c.900G>A p.L300= | Silent (SNP) | VAF 66/301 reads (22%) | called by muse, mutect2, varscan2
- KALRN | c.7569C>G p.V2523= (on ENST00000360013 / NM_001024660.4; = p.V826= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- KLB | c.1911G>A p.A637= | Silent (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- MEIOC | c.1722C>T p.F574= | Silent (SNP) | VAF 103/260 reads (40%) | called by muse, mutect2
- MPL | c.552C>T p.V184= | Silent (SNP) | VAF 32/508 reads (6%) | called by muse, mutect2
- MYO1B | c.1359A>C p.T453= | Silent (SNP) | VAF 97/223 reads (43%) | called by muse, mutect2, varscan2
- NAALADL1 | c.1326C>T p.I442= | Silent (SNP) | VAF 65/284 reads (23%) | called by muse, mutect2, varscan2
- NXPH2 | c.267G>A p.E89= | Silent (SNP) | VAF 31/416 reads (7%) | called by muse, mutect2
- PCDHB4 | c.633C>T p.L211= | Silent (SNP) | VAF 161/437 reads (37%) | catalogued as COSV52019723; called by muse, mutect2, varscan2
- PI15 | c.21C>G p.V7= | Silent (SNP) | VAF 71/301 reads (24%) | called by muse, mutect2, varscan2
- SCARA3 | c.339G>A p.L113= | Silent (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- SEMA4F | c.414C>A p.L138= | Silent (SNP) | VAF 61/272 reads (22%) | called by muse, mutect2, varscan2
- SLC5A11 | c.945G>A p.L315= | Silent (SNP) | VAF 82/319 reads (26%) | called by muse, mutect2, varscan2
- SORT1 | c.276C>T p.F92= | Silent (SNP) | VAF 14/411 reads (3%) | catalogued as rs1272593984; called by muse, mutect2
- TAF6L | c.1656C>T p.F552= | Silent (SNP) | VAF 24/605 reads (4%) | catalogued as rs1209888910; called by muse, mutect2
- TICAM1 | c.534C>G p.L178= | Silent (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- TLNRD1 | c.459G>A p.V153= | Silent (SNP) | VAF 26/559 reads (5%) | called by muse, mutect2
- TMED7 | c.294C>T p.F98= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as rs972770974; called by muse, mutect2
- UNC13B | c.4599G>A p.L1533= | Silent (SNP) | VAF 14/498 reads (3%) | called by muse, mutect2
- ABI3BP | c.*794G>C | 3'UTR (SNP) | VAF 90/300 reads (30%) | called by muse, mutect2, varscan2
- AC244258.1 | n.594C>T | RNA (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- C2CD6 | c.1582-3485G>C | Intron (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- COL20A1 | c.496+20G>C | Intron (SNP) | VAF 30/490 reads (6%) | catalogued as rs1178138626; called by muse, mutect2
- KLHL7 | c.121-5851G>C | Intron (SNP) | VAF 30/385 reads (8%) | catalogued as rs572479542; called by muse, mutect2
- TMEM132D | c.1444-17C>T | Intron (SNP) | VAF 178/414 reads (43%) | called by muse, mutect2, varscan2
